Somatic mutation profile of tumor specimen TCGA-D5-6536-01A (aliquot TCGA-D5-6536-01A-11D-1719-10) from TCGA case TCGA-D5-6536, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.6 years (26,890 days).
Specimen TCGA-D5-6536-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) caceecdb-7d84-418a-ab4c-c9136cd7be14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6536-10A (Blood Derived Normal), aliquot TCGA-D5-6536-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fb3187e-4089-40d8-a185-64a0509cd1a7

The open-access MAF lists 103 somatic variants for this specimen: 87 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 76, Silent 16, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC092143.1 | c.1641C>G p.Y547* | Nonsense Mutation (SNP) | VAF 99/267 reads (37%) | catalogued as COSV59247197; called by muse, mutect2, varscan2
- ACAP2 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.053); catalogued as rs773516430, COSV58749714; called by muse, mutect2, varscan2
- ALS2 | c.1496C>A p.A499D | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV99968901; called by muse, mutect2, varscan2
- APBB1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 64/82 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376108082, COSV100193690; called by muse, varscan2
- ATR | c.2298C>A p.F766L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100637771, COSV63388028; called by muse, mutect2, varscan2
- BCL9L | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52682435; called by muse, mutect2, varscan2
- CASKIN1 | c.3662C>T p.P1221L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1221734380, COSV58212981; called by muse, mutect2, varscan2
- CDC14B | c.683G>A p.C228Y | Missense Mutation (SNP) | VAF 98/290 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV55785123; called by muse, mutect2, varscan2
- CDH2 | c.1769C>T p.T590M | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs201191002, COSV52272404; called by muse, mutect2, varscan2
- CFAP58 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs759795638, COSV57211483; called by muse, mutect2, varscan2
- CHST2 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV58884817; called by muse, mutect2, varscan2
- CNTN6 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100610269, COSV63183518; called by muse, mutect2, varscan2
- CPA1 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 92/270 reads (34%) | catalogued as COSV50568246; called by muse, mutect2, varscan2
- CPXM2 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778302866, COSV53857191; called by muse, mutect2, varscan2
- CST11 | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 106/450 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV63140019; called by muse, mutect2, varscan2
- CYLD | c.2815C>T p.L939F | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781112484, CD148769, COSV100282239; called by muse, mutect2, varscan2
- CYP4F11 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs367904490; called by muse, mutect2, varscan2
- DNAH11 | c.4126G>A p.V1376I | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs531283952, COSV60938522, COSV60977719; called by muse, mutect2, varscan2
- DOK2 | c.387C>A p.S129R | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV52387789; called by muse, mutect2, varscan2
- DSTYK | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 147/220 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs779720873, COSV100904491; called by muse, varscan2
- FGF14 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as COSV101085060; called by muse, mutect2, varscan2
- FUT8 | c.1679A>G p.E560G (on ENST00000360689 / NM_001371534.1; = p.E397G on NM_004480.4) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV61281204; called by muse, mutect2
- GYPA | c.161C>A p.A54E | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.286); catalogued as COSV51621087; called by muse, mutect2, varscan2
- HAPLN3 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs199664746, COSV62084501; called by muse, mutect2, varscan2
- HEATR5A | c.4541G>C p.S1514T | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as COSV66338867; called by muse, mutect2, varscan2
- INTS6L | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 76/116 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.325); catalogued as COSV66083804; called by muse, mutect2, varscan2
- ITPR1 | c.7273G>A p.E2425K (on ENST00000354582; = p.E2370K on NM_002222.7) | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV56971996; called by muse, mutect2, varscan2
- JSRP1 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV55553771; called by muse, mutect2, varscan2
- KIF6 | c.853A>G p.I285V | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.09); catalogued as COSV54668822; called by muse, mutect2, varscan2
- KRT39 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 100/311 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV62916883; called by muse, mutect2, varscan2
- KRTAP19-1 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 94/242 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs371788350, COSV66861122; called by muse, varscan2
- LAMB2 | c.3233G>A p.R1078H | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs373712709; called by muse, mutect2, varscan2
- LBH | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs750086364, COSV101257761; called by muse, mutect2, varscan2
- LONRF1 | c.1840C>G p.Q614E | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV68036067; called by muse, mutect2, varscan2
- LRGUK | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs367635019; called by muse, mutect2, varscan2
- LRRC10 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs565500326, COSV64060077; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LZTS1 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs887212256, COSV56117883; called by muse, mutect2, varscan2
- MATN4 | c.1468G>A p.V490M (on ENST00000372754; = p.V449M on NM_003833.4) | Missense Mutation (SNP) | VAF 19/100 reads (19%) | PolyPhen probably damaging (0.981); catalogued as COSV61350516; called by muse, mutect2, varscan2
- MIGA2 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs749592844, COSV52976031; called by muse, mutect2, varscan2
- MMP16 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754978084, COSV54149112, COSV54151438; called by muse, mutect2, varscan2
- MMS22L | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | catalogued as COSV51517291; called by muse, mutect2, varscan2
- MRGPRX1 | c.757G>T p.V253F | Missense Mutation (SNP) | VAF 135/180 reads (75%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs780207633, COSV57106136; called by muse, mutect2, varscan2
- MYH11 | c.2062G>A p.G688S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs760793367, COSV55545122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK | c.2855A>C p.D952A | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60605655; called by muse, mutect2, varscan2
- NDN | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100086175, COSV59358609; called by muse, mutect2, varscan2
- NOTCH3 | c.4636C>T p.R1546C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs774475688, COSV54628021; called by muse, mutect2, varscan2
- OR4P4 | c.291A>G p.I97M | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1171972926, COSV58920874; called by muse, mutect2, varscan2
- OR5L2 | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 76/305 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1448980294, COSV65723494; called by muse, mutect2, varscan2
- OSMR | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV99952768; called by muse, mutect2, varscan2
- OTOR | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55721697; called by muse, mutect2, varscan2
- PC | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs193271416, COSV58992105; called by muse, mutect2, varscan2
- PCDH11X | c.2810G>A p.R937Q | Missense Mutation (SNP) | VAF 165/219 reads (75%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV53447097; called by muse, mutect2, varscan2
- PCDHA5 | c.2080G>T p.D694Y | Missense Mutation (SNP) | VAF 127/341 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV65349957; called by muse, mutect2, varscan2
- PCSK1 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60734032; called by muse, mutect2, varscan2
- PDZD4 | c.2129A>G p.Q710R | Missense Mutation (SNP) | VAF 128/168 reads (76%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99381116; called by muse, mutect2, varscan2
- PLXNC1 | c.1204-1G>T p.X402_splice | Splice Site (SNP) | VAF 34/105 reads (32%) | catalogued as COSV51570511; called by muse, mutect2, varscan2
- PPP2R5A | c.586T>A p.F196I | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54814450; called by muse, varscan2
- PPP2R5A | c.587T>A p.F196Y | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54814468; called by muse, varscan2
- RHOT1 | c.1463T>C p.I488T | Missense Mutation (SNP) | VAF 96/247 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV61714015; called by muse, mutect2, varscan2
- SAMD9 | c.4160A>T p.N1387I | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66073371; called by muse, mutect2, varscan2
- SCN2A | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769069833, COSV51834027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1252852069, COSV67358567; called by muse, mutect2, varscan2
- SLA2 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53410293; called by muse, mutect2, varscan2
- SLC9C2 | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV62944235; called by muse, mutect2, varscan2
- SLK | c.205T>G p.S69A | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV100211549; called by muse, mutect2, varscan2
- TATDN3 | c.205G>T p.V69F | Missense Mutation (SNP) | VAF 68/400 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV100875191; called by mutect2, varscan2
- TCHH | c.2907G>T p.K969N | Missense Mutation (SNP) | VAF 126/566 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV64273312; called by muse, mutect2, varscan2
- TMPRSS15 | c.689T>A p.L230* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV53035650; called by muse, varscan2
- TMPRSS15 | c.688T>A p.L230M | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.207); catalogued as COSV53035659; called by muse, varscan2
- TNN | c.1159C>G p.P387A | Missense Mutation (SNP) | VAF 58/95 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV99511291; called by muse, mutect2, varscan2
- TRMT5 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 75/247 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV50781285; called by muse, mutect2, varscan2
- UNC79 | c.6247C>T p.R2083C (on ENST00000393151 / NM_001346218.2; = p.R1906C on NM_020818.5) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774094564, COSV56376638; called by muse, mutect2, varscan2
- WIF1 | c.642T>G p.C214W | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54130069; called by muse, mutect2, varscan2
- YIPF7 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100274377; called by mutect2, varscan2
- ZNF318 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.022); catalogued as rs1562133757, COSV58930577; called by muse, mutect2, varscan2
- ZNF354A | c.1781C>G p.T594S | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV59982318; called by muse, mutect2, varscan2
- ZNF532 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 78/158 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs753958965, COSV100266065; called by muse, mutect2, varscan2
- ZNF618 | c.1706A>G p.Y569C (on ENST00000374126 / NM_001318042.2; = p.Y476C on NM_133374.2) | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55917113; called by muse, mutect2, varscan2
- ZNF644 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV100494306; called by muse, varscan2
- ZNF644 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV61346282; called by muse, mutect2, varscan2
- APC | c.4253_4254dup p.S1419* | Frame Shift Ins (INS) | VAF 30/122 reads (25%) | called by mutect2, pindel, varscan2
- EEF1A1 | c.788del p.P263Lfs*27 | Frame Shift Del (DEL) | VAF 144/487 reads (30%) | called by mutect2, pindel, varscan2
- ITGB4 | c.1996del p.E666Rfs*103 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- MARK3 | c.1271dup p.A425Sfs*19 | Frame Shift Ins (INS) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- SOS1 | c.1015_1016del p.L339Tfs*16 | Frame Shift Del (DEL) | VAF 106/324 reads (33%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.307dup p.E103Gfs*23 | Frame Shift Ins (INS) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.7080A>G p.Q2360= | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as COSV51841540; called by muse, mutect2, varscan2
- CCDC185 | c.1092G>A p.A364= | Silent (SNP) | VAF 64/163 reads (39%) | catalogued as rs762525710, COSV64820407; called by muse, mutect2, varscan2
- DIS3L | c.963G>A p.S321= (on ENST00000319212 / NM_001143688.3; = p.S238= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs1249306653, COSV59911276; called by muse, mutect2, varscan2
- DUSP12 | c.132G>A p.E44= | Silent (SNP) | VAF 53/276 reads (19%) | catalogued as rs1382480892, COSV63411163; called by muse, mutect2, varscan2
- FCGR1A | c.415C>A p.R139= | Silent (SNP) | VAF 132/781 reads (17%) | catalogued as rs370037400, COSV100977267; called by muse, mutect2, varscan2
- HAPLN4 | c.114C>T p.H38= | Silent (SNP) | VAF 68/161 reads (42%) | catalogued as COSV52268623; called by muse, mutect2, varscan2
- HMCN1 | c.12123C>T p.G4041= | Silent (SNP) | VAF 150/251 reads (60%) | catalogued as rs183435608, COSV54881568; called by muse, mutect2, varscan2
- LANCL2 | c.969C>T p.G323= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as rs748834351, COSV54647942; called by muse, mutect2, varscan2
- MAGEB6 | c.597G>A p.A199= | Silent (SNP) | VAF 42/53 reads (79%) | catalogued as rs370599063, COSV66871971; called by muse, mutect2, varscan2
- NKX6-3 | c.732C>A p.I244= (on ENST00000518699 / NM_001364841.2; = p.I114= on NM_152568.3) | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as rs770102893, COSV72895079, COSV72895083; called by muse, mutect2, varscan2
- PCDHB5 | c.2031G>A p.P677= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV50647837; called by muse, mutect2, varscan2
- PPP2R5A | c.585T>A p.L195= | Silent (SNP) | VAF 60/267 reads (22%) | catalogued as COSV99806467; called by muse, varscan2
- RYK | c.462G>A p.R154= | Silent (SNP) | VAF 135/378 reads (36%) | catalogued as rs888632597, COSV99938301; called by muse, mutect2, varscan2
- SNIP1 | c.429C>T p.H143= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as COSV56165754; called by muse, mutect2, varscan2
- TMPRSS15 | c.690G>A p.L230= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV53035642; called by muse, varscan2
- ZNF644 | c.1365G>T p.R455= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as COSV61346280; called by muse, varscan2
